Somatic mutation profile of tumor specimen HTMCP-03-06-02072-01A (aliquot HTMCP-03-06-02072-01A-01D-4427) from CGCI case HTMCP-03-06-02072, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02072-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae8404e2-81e0-4f6c-aa09-3aadfcfb37dd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02072-10A (Blood Derived Normal), aliquot HTMCP-03-06-02072-10A-01D-4427; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7e5c18a-9396-4c56-9050-aa7c842c2d90

The open-access MAF lists 41 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Nonsense Mutation 2, 3'UTR 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.5363C>G p.S1788* | Nonsense Mutation (SNP) | VAF 18/122 reads (15%) | catalogued as rs199774535; ClinVar: pathogenic; called by mutect2, varscan2
- ARHGEF40 | c.3851G>A p.R1284Q | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs779797217; called by mutect2, varscan2
- BCR | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs764959319; called by muse, mutect2, varscan2
- BRCA2 | c.6328G>C p.D2110H | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV101204731; called by muse, mutect2, varscan2
- CACNA1I | c.2645C>T p.S882L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1206084619; called by muse, mutect2, varscan2
- CASP8 | c.1181C>T p.P394L (on ENST00000432109 / NM_033355.3; = p.P411L on NM_001228.4) | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51846287, COSV51861191; called by muse, mutect2
- FANCA | c.2647C>G p.L883V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as rs761524155; called by mutect2, varscan2
- KCNV1 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV52085485; called by muse, mutect2, varscan2
- PPFIA1 | c.3007C>G p.R1003G | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs201453636, COSV54131830; called by mutect2, varscan2
- PTPRB | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760734939, COSV54238560; called by muse, mutect2, varscan2
- RUFY3 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs763445500; called by muse, mutect2, varscan2
- SEZ6L | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.063); catalogued as rs764095767, COSV50657840; called by mutect2, varscan2
- SMARCA4 | c.3382G>A p.G1128R | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60806253; called by muse, mutect2, varscan2
- ZNF804B | c.348T>A p.H116Q | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60821137; called by muse, mutect2
- ARFIP2 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CDH7 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CFAP47 | c.8308A>C p.T2770P | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL20A1 | c.288C>A p.F96L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.092); called by mutect2, varscan2
- DDB1 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK3 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2
- FAM120C | c.1916T>C p.I639T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- GRB14 | c.1425C>G p.F475L | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- GTF3C1 | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- INTS6 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 59/324 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MACF1 | c.18517C>T p.Q6173* (on ENST00000372915; = p.Q4218* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- MALRD1 | c.5282C>T p.P1761L | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- PKDREJ | c.1925A>C p.Q642P | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.284); called by muse, mutect2
- RASA1 | c.2174_2184del p.E725Afs*38 | Frame Shift Del (DEL) | VAF 19/122 reads (16%) | called by mutect2, pindel, varscan2
- SI | c.1601T>C p.I534T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WNK4 | c.2648C>T p.S883F | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- ADGRV1 | c.16680G>A p.V5560= | Silent (SNP) | VAF 13/237 reads (5%) | catalogued as COSV67992135; called by muse, mutect2
- AKAP9 | c.1014A>T p.I338= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- CACNA2D1 | c.573A>G p.E191= | Silent (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- CCDC125 | c.822G>A p.A274= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as rs930046572; called by muse, mutect2, varscan2
- EEF2K | c.1116G>C p.L372= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs1260740980; called by muse, mutect2
- EPHB4 | c.1734C>T p.H578= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs781138617; called by mutect2, varscan2
- OR4S1 | c.756C>T p.P252= | Silent (SNP) | VAF 36/308 reads (12%) | catalogued as COSV60678736; called by muse, mutect2
- TTN | c.81366C>A p.T27122= (on ENST00000591111; = p.T19698= on NM_003319.4) | Silent (SNP) | VAF 46/262 reads (18%) | called by muse, mutect2, varscan2
- ALS2 | c.*4G>T | 3'UTR (SNP) | VAF 11/146 reads (8%) | called by muse, mutect2
- CCPG1 | c.*3277T>G | 3'UTR (SNP) | VAF 25/154 reads (16%) | called by muse, mutect2, varscan2
- GPR65 | c.1del | 5'UTR (DEL) | VAF 25/159 reads (16%) | called by mutect2, pindel, varscan2
